Somatic mutation profile of tumor specimen TCGA-YL-A9WL-01A (aliquot TCGA-YL-A9WL-01A-11D-A41K-08) from TCGA case TCGA-YL-A9WL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.2 years (21,626 days).
Specimen TCGA-YL-A9WL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d3921ae-f072-41d3-a93d-c0df07c9a301.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A9WL-10A (Blood Derived Normal), aliquot TCGA-YL-A9WL-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc6f781-c668-4b2a-822f-a8077f45a94b

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Splice Site 3, Silent 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as rs1330876736, COSV99503923; called by muse, mutect2, varscan2
- ALCAM | c.72A>C p.P24= | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as rs1559766668; called by muse, mutect2
- ATXN2L | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs765799433, COSV100295000; called by muse, mutect2, varscan2
- CSMD3 | c.7360+1G>T p.X2454_splice (on ENST00000297405 / NM_001363185.1; = p.X2350_splice on NM_052900.3) | Splice Site (SNP) | VAF 25/36 reads (69%) | catalogued as COSV99844835; called by muse, mutect2, varscan2
- GABRE | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs1358214415, COSV100944351; called by muse, mutect2, varscan2
- HPCAL4 | c.257T>A p.I86N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100864809; called by muse, mutect2, varscan2
- KCNG1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs761694072, COSV65367996; called by muse, mutect2, varscan2
- KRT33B | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99290783; called by muse, mutect2
- MS4A6A | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs530964700, COSV60619005; called by muse, mutect2, varscan2
- MSH4 | c.1305+1G>T p.X435_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99592333; called by muse, mutect2, varscan2
- OR5L1 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.981); catalogued as COSV100450213; called by muse, mutect2, varscan2
- PCDHA11 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV56538350; called by muse, mutect2
- STAT4 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV100636149; called by muse, mutect2, varscan2
- TMEM200C | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101274841, COSV67310135; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1363T>A p.W455R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100389857; called by muse, mutect2, varscan2
- TTLL5 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99709761; called by muse, mutect2
- UBA2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV99875751; called by muse, mutect2, varscan2
- PRPF8 | c.3300-30_3301del p.X1100_splice | Splice Site (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel
- CAV2 | c.243A>G p.K81= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99760855; called by muse, mutect2
- GLDC | c.2247C>T p.H749= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100394489; called by muse, mutect2, varscan2
- MED13L | c.1851A>G p.L617= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99929916; called by muse, mutect2, varscan2
- NACA | c.71-1502G>A | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as rs775269882, COSV100771573; called by muse, mutect2, varscan2
